Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABE, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABE-01A (Primary Tumor).

[page 1 of 2]
Surgery date:

Surgical Pathology

ICD-O-3
Adenocarcinoma duct NOS
8500/3
Site: Pancreas body
p5.1
5/5/14

DIAGNOSIS:

A. Soft tissue, falciform ligament, excision: Benign elastotic nodule.

B. Pancreatic body and tail and spleen, partial pancreatectomy and splenectomy: Invasive moderately differentiated ductal adenocarcinoma is identified forming a mass (5.8 x 3.6 x 3.3 cm) located in the pancreatic body. The tumor extends beyond the pancreas to involve the peripancreatic soft tissue. Perineural invasion is present. Tumor necrosis is absent. All surgical resection margins are negative for tumor (minimum tumor free margin, 2.1 cm, proximal pancreatic margin). The adjacent non-neoplastic pancreatic parenchyma contains PanIN 1A. Multiple (23) regional lymph nodes are negative for tumor.

C. Lymph node, peripancreatic, excision: A single (1) lymph node is negative for tumor.

With available surgical material, [AJCC pT3N0] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "falciform ligament" is a 0.4 x 0.4 x 0.2 cm fragment of tan soft tissue. All submitted. Grossed by

B. Received fresh labeled "spleen, distal pancreas" is a distal pancreatectomy specimen consisting of 10.8 x 5.3 x 2.0 cm portion of pancreas and a 170.0 gram, 11.5 x 8.8 x 2.5 cm partially morcellated spleen. A 5.8 x 3.6 x 3.3 cm tan-white, solid, and cystic, firm mass is present within the pancreas, 2.1 cm from the proximal pancreatic margin. The mass does not appear to be confined to the pancreas, grossly. The peripancreatic soft tissue is inked. Peripancreatic lymph nodes and splenic hilar lymph nodes are identified. The spleen is grossly unremarkable. Representative sections are submitted. Grossed by

C. Received fresh labeled "peripancreatic lymph nodes" is a 2.6 x 1.1 x 0.8 cm aggregate of adipose tissue, lymphatic tissue not

[page 2 of 2]
identified grossly. All submitted. Grossed by

BLOCK SUMMARY:

Part A: Falciform ligament

1 Falciform ligament

Part B: Distal pancreas and spleen

1 Proximal pancreatic margin

2 Mass-1

3 Mass-2

4 Mass-3

5 Spleen

6 Mass to splenic artery

7 Splenic LNs-1(B7)

8 Splenic LNs-1(B8)

9 Splenic LNs-5(B9)

10 Peripancreatic LNs-5(B1)

11 Peripancreatic LNs-3(B2)

12 Peripancreatic LNs-4(B3)

13 Peripancreatic LNs-3(B4)

14 Peripancreatic LNs-3(B5)

15 Peripancreatic LNs-1(B6)

Part C: Peri pancreatic lymph node

1 Peripancreatic tissue

Source: NCI Genomic Data Commons file 5056bce3-be34-4dad-bacf-c937d6a4bf3b (TCGA-2J-AABE.16730789-69FC-4C59-9411-4472A4130F81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).